CGCI case HTMCP-01-06-00105 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0ea7453a-e7d4-4cbf-ab37-0019c1190ec6

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 36 years.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 36.5 years (13,327 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage III; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 202 days; Ann Arbor extranodal involvement: Yes; Sites of involvement: Stomach.
   Pathology details: Lymph node involved site: Cervical, NOS; Tumor largest dimension diameter: 7 cm.
   Pathology details: Lymph node involved site: Splenic.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOP-21; Days to treatment start: 40 days; Days to treatment end: 202 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 40 days; Days to treatment end: 202 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 202 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: day 17.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Negative; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- Lactate Dehydrogenase 2209 [Blood test normal range upper: 298].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day 0: Weight: 64 kg; Height: 160 cm; BMI: 25; Haart treatment indicator: Yes; HIV viral load: 34.
- Day 17: Risk factors: HIV/AIDS.
- Day 17: Comorbidities: HIV/AIDS.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-01-06-00105-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-06-00105-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-06-00105-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Tobacco smoking history indicator: 1; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- History of disease: Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Other Extranodal Site.
- Primary pathology: Extranodal involvment other: Epigastric mass; Extranodal site involvement: 1; Method initial path diagnosis: Biopsy (all types); Lymph nodes examined: No.
- Tests performed: LDH level: 2209.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharma adjuvant cycles count: 6.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_GDC_Submission001_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-01-06-00105-01A-01R-4427:
- % tumour top: 75
- % tumour bottom: 75

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_GDC_Submission001_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-01-06-00105-01A-01D-4427:
- % tumour top: 75
- % tumour bottom: 75

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_GDC_Submission001_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-01-06-00105-10A-01D-4427:
- % tumour top: 0
- % tumour bottom: 0
